Somatic mutation profile of tumor specimen TCGA-JY-A93D-01A (aliquot TCGA-JY-A93D-01A-11D-A387-09) from TCGA case TCGA-JY-A93D, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 51.5 years (18,813 days).
Specimen TCGA-JY-A93D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c25b60c0-9330-4fd9-b0e4-81be45f0bc52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JY-A93D-10A (Blood Derived Normal), aliquot TCGA-JY-A93D-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5279fd72-6cb8-4f70-a6e1-e61b0fdccdfa

The open-access MAF lists 108 somatic variants for this specimen: 80 protein-altering or splice-affecting, 25 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 25, Nonsense Mutation 5, RNA 2, Frame Shift Del 2, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 11/53 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.14460T>G p.Y4820* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | catalogued as COSV68948828; called by muse, mutect2, varscan2
- ANO8 | c.3122G>A p.R1041H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs778843591; called by muse, mutect2, varscan2
- BAMBI | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs575182425; called by mutect2, varscan2
- BCAM | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs773224737, COSV54302188; called by muse, mutect2, varscan2
- COG4 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs149620212; called by muse, mutect2, varscan2
- COL21A1 | c.1606G>T p.G536C | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99779330; called by muse, mutect2
- DACT1 | c.2152G>A p.A718T | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs147227144; called by mutect2, varscan2
- DCHS1 | c.6509G>A p.R2170H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs147106756; called by muse, mutect2, varscan2
- DMD | c.9584G>A p.R3195H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756958090, COSV58892970, COSV58926071; called by muse, mutect2, varscan2
- DNAH5 | c.12599A>C p.K4200T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54201514, COSV54202045, COSV54212456; called by muse, varscan2
- EDA2R | c.475T>G p.F159V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV53630218; called by muse, mutect2, varscan2
- F13B | c.1474T>G p.L492V | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV100803501, COSV66375643; called by muse, mutect2, varscan2
- FGA | c.1119G>A p.W373* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as rs745804153, CM155315; called by muse, mutect2, varscan2
- GOLGA8A | c.1730C>G p.P577R (on ENST00000432566; = p.P549R on NM_181077.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); catalogued as rs1199173124; called by muse, mutect2, varscan2
- IVL | c.996A>C p.Q332H | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV64216411; called by muse, mutect2
- KY | c.320A>C p.K107T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV71017125; called by mutect2, varscan2
- LLGL2 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.545); catalogued as rs761967911, COSV51341943, COSV51344620; called by muse, mutect2
- LRP11 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.728); catalogued as rs200823832; called by muse, mutect2, varscan2
- LRRK2 | c.5327T>A p.L1776H | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV54165377; called by muse, mutect2
- MAG | c.1456G>A p.V486I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.033); catalogued as rs142036180; called by muse, mutect2, varscan2
- MTUS2 | c.3044C>T p.A1015V | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs201118258, COSV70919028; called by muse, mutect2, varscan2
- MUC6 | c.6387_6389del p.S2130del | In Frame Del (DEL) | VAF 6/27 reads (22%) | catalogued as rs765184193; called by pindel, varscan2
- NAA15 | c.1896T>G p.D632E | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs759801535; called by muse, mutect2, varscan2
- OR10X1 | c.477A>C p.Q159H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV63767884; called by muse, mutect2, varscan2
- OR4C13 | c.80T>A p.V27D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV73648664; called by muse, mutect2, varscan2
- OR6M1 | c.791C>A p.S264* | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100484174; called by muse, mutect2, varscan2
- PCDH15 | c.5434C>T p.P1812S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.005); catalogued as COSV100219220, COSV57279464; called by muse, mutect2
- PCDHB7 | c.254T>G p.L85R | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.699); catalogued as COSV50753495; called by muse, mutect2, varscan2
- PCLO | c.11320G>A p.E3774K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV61617419; called by muse, mutect2, varscan2
- PLA2G6 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as rs372291638, CM165794; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PROX1 | c.767A>C p.K256T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs1313541445; called by muse, mutect2, varscan2
- TSPOAP1 | c.3665G>T p.G1222V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.448); catalogued as rs201358584; called by muse, mutect2, varscan2
- TXNDC16 | c.2275C>T p.R759C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.083); catalogued as rs367573078; called by muse, mutect2, varscan2
- USP29 | c.385A>C p.I129L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as COSV54241797; called by muse, mutect2, varscan2
- VWF | c.4049C>T p.A1350V | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs764155969, COSV54624628; called by muse, mutect2, varscan2
- ZNF804B | c.2448A>C p.Q816H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.72); catalogued as COSV60824477; called by muse, mutect2, varscan2
- ZSCAN18 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.051); catalogued as rs375610615, COSV99067338; called by muse, mutect2, varscan2
- ABCA2 | c.5702C>T p.T1901I (on ENST00000614293; = p.T1871I on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- AP001781.2 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 26/114 reads (23%) | called by muse, mutect2, varscan2
- BIRC6 | c.1778G>A p.G593D | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CAPN6 | c.916A>C p.T306P | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- CD1E | c.230T>G p.L77R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CDKN2A | c.332_333del p.G111Afs*8 | Frame Shift Del (DEL) | VAF 15/36 reads (42%) | called by mutect2, pindel, varscan2
- CRB1 | c.2251T>G p.L751V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- EPHB6 | c.2842T>A p.F948I | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FLRT2 | c.1714T>C p.Y572H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- GSTK1 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HBP1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- KAT6A | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KCNT2 | c.857A>G p.K286R | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- KYAT3 | c.64T>C p.S22P | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- LZTS1 | c.818G>A p.R273K | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); called by muse, mutect2
- MATN4 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | PolyPhen benign (0.317); called by muse, mutect2, varscan2
- MLLT6 | c.1567G>A p.G523S | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- MYT1L | c.1220A>G p.E407G | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- OR2M4 | c.888A>C p.E296D | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- OR2T6 | c.854T>G p.L285* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- OR6Y1 | c.820A>T p.N274Y | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PDZD2 | c.3178A>G p.T1060A | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP1R14D | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PRAMEF19 | c.645G>C p.M215I | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PSAT1 | c.440C>G p.S147C | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PXDN | c.1323C>A p.D441E | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- RECQL | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RPH3A | c.148C>A p.L50M (on ENST00000389385 / NM_001143854.2; = p.L46M on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCN2A | c.5383T>A p.F1795I | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SEMA5A | c.209T>C p.L70P | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- SH3BP4 | c.994C>T p.L332F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SNAI2 | c.595T>G p.L199V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TCIRG1 | c.2039A>G p.D680G | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- TIE1 | c.1913T>G p.L638R | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- TIPARP | c.1558G>T p.G520C | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.815); called by muse, mutect2
- TPO | c.689T>G p.L230R | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- UNC5C | c.1610A>C p.N537T | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.192); called by muse, mutect2
- USP51 | c.227G>A p.S76N | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS13B | c.2623del p.S875Qfs*2 | Frame Shift Del (DEL) | VAF 14/85 reads (16%) | called by mutect2, pindel*, varscan2
- ZNF292 | c.1412A>G p.D471G | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF470 | c.1688A>T p.K563M | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF626 | c.381A>C p.K127N | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- ALG13 | c.825T>A p.T275= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV99323321; called by muse, mutect2, varscan2
- BCL9 | c.3384G>A p.P1128= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs782462964; called by muse, mutect2, varscan2
- BTNL3 | c.579C>A p.I193= | Silent (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2, varscan2
- CASS4 | c.387A>G p.Q129= | Silent (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- GCLC | c.1785A>C p.I595= (on ENST00000643939; = p.I593= on NM_001498.4) | Silent (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- ITGA7 | c.1425C>T p.G475= (on ENST00000555728; = p.G431= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs757453079; called by muse, mutect2, varscan2
- KCND2 | c.453C>T p.D151= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV58591649; called by muse, mutect2, varscan2
- KRTAP19-4 | c.240T>C p.N80= | Silent (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- LRP1B | c.11626A>C p.R3876= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV67281282; called by muse, mutect2, varscan2
- LRRC55 | c.150T>C p.D50= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as rs779999952; called by muse, mutect2, varscan2
- MCF2 | c.2709T>C p.T903= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV58477125; called by muse, mutect2, varscan2
- MECOM | c.2196C>A p.R732= (on ENST00000468789 / NM_001105078.4; = p.R920= on NM_004991.4) | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV52972206; called by muse, mutect2
- MEGF6 | c.1371G>A p.P457= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs772769708; called by muse, varscan2
- MYOM2 | c.141C>G p.S47= | Silent (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2
- NOTCH3 | c.972C>T p.F324= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs149725987, COSV54637239; called by muse, mutect2, varscan2
- PCDHB8 | c.1791G>A p.S597= | Silent (SNP) | VAF 12/180 reads (7%) | catalogued as COSV99175300; called by muse, mutect2
- PLEKHM1 | c.3126C>A p.R1042= | Silent (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- RIMS1 | c.2094G>T p.R698= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV99324940; called by muse, mutect2, varscan2
- SIGLEC5 | c.1635G>A p.S545= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs768767181; called by muse, mutect2, varscan2
- SLC30A8 | c.444C>A p.I148= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV69977417; called by muse, mutect2, varscan2
- SOBP | c.1566C>T p.T522= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV58004204; called by muse, mutect2, varscan2
- TCF4 | c.525A>G p.K175= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV61891740; called by muse, mutect2, varscan2
- UGT3A1 | c.930G>A p.Q310= | Silent (SNP) | VAF 24/90 reads (27%) | called by muse, mutect2, varscan2
- ZNF205 | c.543G>A p.S181= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs768850791; called by muse, mutect2, varscan2
- ZNF568 | c.1083T>G p.P361= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV100451142; called by muse, mutect2, varscan2
- AL353804.6 | n.54A>T | RNA (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- DCHS2 | n.6288A>C | RNA (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- RNU6-1178P | chr17:20895829 G>A | 5'Flank (SNP) | VAF 17/56 reads (30%) | catalogued as COSV60002685; called by muse, mutect2, varscan2
